TCGA case TCGA-CZ-5461 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/393abcf7-1155-4b32-85ca-cd44d259e4b4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 330 days.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,030 days); Year of diagnosis: 2006; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 33 days; Days to treatment end: 39 days; Treatment dose: 400 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Initial disease status: Progressive Disease; Days to treatment start: 45 days; Days to treatment end: 278 days; Number of cycles: 5; Treatment dose: 7,000 mg; Prescribed dose: 50; Prescribed dose units: mg/day; Route of administration: Oral.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 52.2 years (19,078 days); Days to diagnosis: 48 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 52 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 48 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 48 days.
- Days to follow up: 330 days; Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Calcium: Low.
- Leukocytes: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-5461-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.2.
  Slide TCGA-CZ-5461-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CZ-5461-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-CZ-5461-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-5461-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1.1; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; Days to last known alive: 317; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Performance status timing: Preoperative; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment: Pharmaceutical therapy drug name: sunitinib (sutent); Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 330 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 330 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 48 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CZ-5461-01A-01D-1499-01): tumor purity 0.4, ploidy 5.04, whole-genome doublings 2.
